Gene-level copy-number profile of tumor specimen TCGA-N5-A4RU-01A from TCGA case TCGA-N5-A4RU, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Age at diagnosis: 54.8 years (20,025 days).
Specimen TCGA-N5-A4RU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.66af2cc3-c7fe-4ee2-9ced-bab7d2f98752.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d6385a2-6cd0-4892-bfb2-49e573083619

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,462; copy number 2: 10,463; copy number 3: 28,786; copy number 4: 13,362; copy number 5: 4,434; copy number 6: 378; copy number 7: 248; copy number 8: 110; copy number 9: 503; copy number 10: 51; copy number 11: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RU-01A-31D-A28Q-01): tumor purity 0.72, ploidy 6.24, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:66,630,715–66,630,776, 1 gene: RNU7-87P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 921 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:13,816,258–13,937,477, 3 genes, copy number 8: WNT7A, VN1R20P, FGD5P1.
- chr3:66,622,760–70,808,452, 42 genes, copy number 8–9: AC104440.1, RPL21P41, AC098969.2, AC098969.1, AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P.
- chr7:25,118,656–25,500,443, 11 genes, copy number 7: CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2.
- chr8:126,556,323–127,419,050, 1 gene, copy number 11 (within-gene range 5–11): PCAT1.
- chr8:127,072,694–141,392,574, 163 genes, copy number 8–11 (broad region; genes not listed).
- chr9:129,175,807–129,513,687, 12 genes, copy number 7 (within-gene range 5–7): AL158151.1, AL161785.1, C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2.
- chr9:136,428,619–136,866,308, 40 genes, copy number 7: INPP5E, SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1, RABL6, NCLP1, MIR4292, AJM1, PHPT1, MAMDC4, EDF1.
- chr9:136,886,733–136,886,803, 1 gene, copy number 7: MIR4479.
- chr10:32,887,273–33,336,262, 11 genes, copy number 8 (within-gene range 3–8): ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P.
- chr11:54,591,480–58,344,664, 198 genes, copy number 9 (broad region; genes not listed).
- chr11:63,369,785–63,957,319, 22 genes, copy number 9 (within-gene range 6–9): SLC22A9, PLAAT5, AP000484.1, AP001591.1, LGALS12, PLAAT4, PLAAT2, PLAAT3, AP000753.1, ATL3, IMMP1LP1, AP000753.2, RTN3, AP000753.3, C11orf95, RN7SL596P, SPINDOC, ATP5MGP1, MARK2, RNU6-1306P, RCOR2, NAA40.
- chr12:31,876,969–31,959,316, 1 gene, copy number 7 (within-gene range 4–7): LINC02422.
- chr12:31,948,334–32,396,147, 14 genes, copy number 7: RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA.
- chr16:27,998,295–33,875,468, 393 genes, copy number 7–9 (broad region; genes not listed).
- chr17:15,436,015–15,563,561, 2 genes, copy number 7 (within-gene range 2–8): CDRT4, TVP23C-CDRT4.
- chr17:15,502,264–15,651,653, 7 genes, copy number 7 (within-gene range 6–7): TVP23C, PPIAP53, AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1.

Autosomal genes at a single copy (total copy number 1): 1,138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
